Gene-level copy-number profile of tumor specimen TARGET-10-PATHBG-09A from TARGET case TARGET-10-PATHBG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,081 days).
Specimen TARGET-10-PATHBG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.fb29bda0-1712-5fd8-a7be-a9ce7123761c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATHBG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate.
https://portal.gdc.cancer.gov/files/dd54005a-31e3-4330-8591-2c868729e5d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 94; copy number 2: 57,981; copy number 3: 1,528; copy number 4: 90; copy number 5: 2; copy number 6: 5; copy number 7: 1; copy number 10: 1; copy number 12: 25.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr3:75,370,448–75,590,649, 12 genes: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr4:168,598,240–168,598,757, 1 gene: BTF3L4P4.
- chr5:79,000,112–79,001,124, 1 gene: AC020937.1.
- chr7:38,273,587–38,311,808, 6 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr19:48,180,770–48,255,946, 3 genes (within-gene range 0–2): CARD8, AC011466.4, AC011466.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 2–12): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:10,115,675–10,127,190, 1 gene, copy number 7: BRK1.
- chr6:29,373,423–29,375,291, 1 gene, copy number 5: OR12D3.
- chr7:151,057,210–151,083,493, 5 genes, copy number 6: SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1.
- chr14:22,630,929–22,644,352, 1 gene, copy number 10 (within-gene range 1–10): OR6J1.
- chr16:58,231,157–58,283,836, 1 gene, copy number 5 (within-gene range 2–5): CCDC113.

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
